Gene-level copy-number profile of specimen HCM-SANG-0780-C25-85A-01D-A80T-32 from HCMI case HCM-SANG-0780-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2.
Specimen HCM-SANG-0780-C25-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0ce87aee-094a-4504-af52-a2e5ec5af427.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0780-C25-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,744 have no estimate.
https://portal.gdc.cancer.gov/files/3c23f551-eb21-4be6-bc02-a6b98c3147fb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 608; copy number 2: 16,551; copy number 3: 20,977; copy number 4: 15,733; copy number 5: 2,466; copy number 6: 2,534; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:20,344,736–20,599,195, 8 genes: AC026495.1, HERC2P3, AC023310.1, GOLGA6L6, AC023310.3, GOLGA8CP, RN7SL759P, SPATA31E2P.
- chr15:22,225,278–22,225,329, 1 gene: MIR1268A.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:8,717,684–8,717,883, 1 gene, copy number 8: AC091932.4.

Autosomal genes at a single copy (total copy number 1): 96. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
